Somatic mutation profile of tumor specimen 0DOJW1 from CCDI case PBCCIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,147 days).
Specimen 0DOJW1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b23a96-082b-46bd-8644-798d8f664d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c92a6145-088c-49d0-aa38-a4cf817d87f5

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Intron 5, Silent 2, 5'UTR 2, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 381/1086 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 362/856 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- ANKAR | c.3904C>G p.Q1302E | Missense Mutation (SNP) | VAF 308/911 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV99854140; called by muse, mutect2, varscan2
- CHRNA4 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719917; called by muse, mutect2, varscan2
- CYBB | c.1317C>A p.I439= | Splice Region (SNP) | VAF 212/471 reads (45%) | catalogued as COSV66085883; called by muse, mutect2, varscan2
- GPR179 | c.1918C>T p.R640W (on ENST00000621958; = p.R639W on NM_001004334.4) | Missense Mutation (SNP) | VAF 95/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs751651912; called by muse, mutect2, varscan2
- SLC6A20 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 184/465 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs781437611, COSV62071512; called by muse, varscan2
- TRMT1L | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 246/1643 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV100834630; called by muse, mutect2, varscan2
- TRRAP | c.9529G>A p.V3177M (on ENST00000359863 / NM_001244580.1; = p.V3148M on NM_003496.3) | Missense Mutation (SNP) | VAF 226/563 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs773731618; called by muse, mutect2, varscan2
- TTN | c.69646C>A p.Q23216K (on ENST00000591111; = p.Q15792K on NM_003319.4) | Missense Mutation (SNP) | VAF 284/930 reads (31%) | PolyPhen benign (0.053); catalogued as rs766557412; called by muse, mutect2, varscan2
- USHBP1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs562060158; called by muse, mutect2, varscan2
- ARHGAP18 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 178/513 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATRX | c.2317A>T p.K773* | Nonsense Mutation (SNP) | VAF 288/825 reads (35%) | called by muse, mutect2, varscan2
- CD180 | c.1867del p.L623Ffs*8 | Frame Shift Del (DEL) | VAF 138/716 reads (19%) | called by mutect2, varscan2
- FCSK | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- FNDC1 | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 85/812 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KREMEN2 | c.1288T>A p.C430S (on ENST00000303746 / NM_172229.3; = p.P403= on NM_024507.4) | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 28/990 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 33/1187 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- MYO7A | c.4376T>C p.V1459A | Missense Mutation (SNP) | VAF 193/521 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- NOMO1 | c.1798A>G p.I600V | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- NR0B1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 172/444 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- OR10Z1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 216/820 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PHIP | c.3557C>G p.A1186G | Missense Mutation (SNP) | VAF 342/1023 reads (33%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.841); called by muse, varscan2
- PRMT9 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 194/615 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SETDB2 | c.1428A>C p.K476N | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 56/1296 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ANKRD30A | c.3216T>A p.A1072= (on ENST00000611781; = p.A1016= on NM_052997.2) | Silent (SNP) | VAF 110/1494 reads (7%) | called by muse, mutect2
- ATP8B1 | c.2337C>T p.Y779= | Silent (SNP) | VAF 469/943 reads (50%) | catalogued as rs764863689; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*19+66C>G | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as rs920395245, COSV101374590; called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- KCNS2 | c.*33G>T | 3'UTR (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- KLK2 | c.630+47G>C | Intron (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- KRT23 | c.-36G>A | 5'UTR (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- OR11H2 | chr14:19713908 G>A | 5'Flank (SNP) | VAF 264/794 reads (33%) | catalogued as rs1459632881; called by muse, mutect2, varscan2
- PDIA3 | c.-70C>G | 5'UTR (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- PIDD1 | c.296-56G>A | Intron (SNP) | VAF 18/35 reads (51%) | catalogued as rs1489963468; called by muse, mutect2, varscan2
